Somatic mutation profile of tumor specimen TCGA-SX-A71V-01A (aliquot TCGA-SX-A71V-01A-11D-A33Q-10) from TCGA case TCGA-SX-A71V, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 80.3 years (29,332 days).
Specimen TCGA-SX-A71V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dec1bde1-05fa-4b02-a940-4aedab1bf430.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A71V-10A (Blood Derived Normal), aliquot TCGA-SX-A71V-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a83511a4-afce-4a6a-9047-c41da3369276

The open-access MAF lists 119 somatic variants for this specimen: 95 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 77, Silent 24, Frame Shift Del 9, Nonsense Mutation 3, Frame Shift Ins 2, Splice Site 2, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD3 | c.550C>A p.L184I | Missense Mutation (SNP) | VAF 18/300 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV56677815; called by muse, mutect2
- AKAP11 | c.5218A>T p.S1740C | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99214316; called by muse, mutect2, varscan2
- ANO10 | c.1480A>G p.T494A | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV99428997; called by muse, mutect2, varscan2
- AP5B1 | c.254T>C p.L85P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100376150; called by muse, mutect2
- ARHGAP33 | c.3074C>T p.S1025F | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as rs1410174666, COSV99139924; called by muse, mutect2, varscan2
- ATF2 | c.1208A>C p.N403T | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as COSV99909002; called by muse, mutect2, varscan2
- ATF6 | c.800A>G p.N267S | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100909475; called by muse, mutect2, varscan2
- BCL9L | c.2497C>G p.Q833E | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.582); catalogued as COSV99420063; called by muse, mutect2, varscan2
- C11orf58 | c.452T>G p.L151R | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV99930385; called by muse, mutect2, varscan2
- C2orf78 | c.2248T>G p.Y750D | Missense Mutation (SNP) | VAF 50/217 reads (23%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV101281031; called by muse, mutect2, varscan2
- CACNA1E | c.98C>G p.S33W | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV100705167; called by muse, mutect2, varscan2
- CASP8AP2 | c.2684C>G p.A895G | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV99387538; called by muse, mutect2, varscan2
- CASS4 | c.695G>T p.S232I | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV100824912; called by muse, mutect2, varscan2
- CCDC197 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.626); catalogued as COSV100113699; called by muse, mutect2, varscan2
- CDH23 | c.6082G>A p.D2028N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99823649; called by muse, mutect2, varscan2
- COMMD8 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV101055778; called by muse, mutect2, varscan2
- COX10 | c.953T>A p.L318H | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99887044; called by muse, mutect2, varscan2
- CPXCR1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 72/104 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99342409; called by muse, mutect2, varscan2
- DKKL1 | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.437); catalogued as COSV99678792; called by muse, mutect2, varscan2
- DNAH1 | c.9157G>C p.V3053L | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV101327013; called by muse, mutect2, varscan2
- DST | c.20483G>C p.W6828S (on ENST00000361203 / NM_001374722.1; = p.W4525S on NM_015548.5) | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99759734; called by muse, mutect2, varscan2
- FAM83A | c.472A>C p.T158P | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV99414594; called by muse, mutect2, varscan2
- FAM83A | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99414598; called by muse, mutect2, varscan2
- FAT3 | c.12202C>T p.P4068S | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs267603245, COSV99970738; called by muse, varscan2
- FGF7 | c.35C>G p.T12S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99983617; called by muse, mutect2, varscan2
- FLII | c.2288T>C p.M763T | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.103); catalogued as COSV100375646; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1157C>A p.T386N | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs922125141, COSV100437911; called by muse, mutect2, varscan2
- FREM1 | c.4616C>T p.A1539V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs753002186, COSV101085423; called by muse, mutect2
- GATM | c.224T>G p.L75* | Nonsense Mutation (SNP) | VAF 28/67 reads (42%) | catalogued as COSV101188411; called by muse, mutect2, varscan2
- GPI | c.1109G>A p.R370H | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs747466827, COSV62893796; called by muse, mutect2, varscan2
- HAX1 | c.634T>C p.S212P | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99672245; called by muse, mutect2, varscan2
- HIPK1 | c.299T>A p.F100Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.221); catalogued as COSV101060561; called by muse, mutect2, varscan2
- HOXA7 | c.437A>G p.E146G | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99636748; called by muse, mutect2, varscan2
- HSPB2 | c.146T>C p.V49A | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV99909968; called by muse, mutect2, varscan2
- IFNG | c.115A>C p.N39H | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99971297; called by mutect2, varscan2
- KCNQ1 | c.1744G>C p.D582H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV99328368; called by muse, mutect2, varscan2
- KIAA1614 | c.3155A>T p.H1052L | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV100799894; called by muse, mutect2, varscan2
- KRT78 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.42); catalogued as COSV100467608; called by muse, mutect2, varscan2
- LRP10 | c.358G>A p.G120R | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100612492; called by muse, mutect2, varscan2
- LRP10 | c.529G>C p.D177H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV62078370; called by muse, mutect2, varscan2
- LRRC20 | c.314C>G p.S105C (on ENST00000355790 / NM_207119.3; = p.S55C on NM_018239.4) | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100714256; called by muse, mutect2, varscan2
- MAN2A1 | c.2338A>C p.T780P | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV99811859; called by muse, mutect2, varscan2
- MAPK14 | c.271A>C p.T91P | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV100005181; called by muse, mutect2, varscan2
- MUC20 | c.1549A>G p.T517A | Missense Mutation (SNP) | VAF 103/263 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.136); catalogued as rs1277094305, COSV100291485; called by muse, mutect2, varscan2
- NAT10 | c.2651T>A p.I884N | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs1264806196, COSV99140483, COSV99140640; called by muse, mutect2, varscan2
- NIPAL3 | c.245T>A p.L82Q | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99135492; called by muse, mutect2, varscan2
- NKD1 | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs755243322, COSV99194124; called by muse, mutect2, varscan2
- NUP210L | c.5125C>G p.Q1709E | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV99669048; called by muse, mutect2, varscan2
- OXR1 | c.1339A>G p.N447D (on ENST00000442977 / NM_001198532.1; = p.N446D on NM_018002.3) | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100367704; called by muse, mutect2, varscan2
- PCDHGA2 | c.1816T>C p.Y606H | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99546411; called by muse, mutect2, varscan2
- PCLO | c.11528G>A p.R3843K | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1245507155, COSV100437478, COSV100437504; called by muse, mutect2, varscan2
- PGLYRP3 | c.55G>A p.D19N | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.202); catalogued as COSV51952483; called by muse, mutect2, varscan2
- PKN3 | c.1679G>A p.R560H | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs757126152, COSV52580274; called by muse, mutect2, varscan2
- PLD1 | c.2527A>G p.M843V | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV100578842; called by muse, mutect2, varscan2
- POM121 | c.2665G>T p.A889S (on ENST00000434423; = p.A624S on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.757); catalogued as COSV99989210; called by muse, mutect2, varscan2
- PPP2R5C | c.955G>C p.E319Q | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.492); catalogued as COSV100159973; called by muse, mutect2, varscan2
- PRDM5 | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1268548844, COSV99311358; called by muse, mutect2, varscan2
- RDH12 | c.444C>A p.H148Q | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99961934; called by muse, mutect2, varscan2
- RIC8A | c.452A>C p.Y151S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV100254914; called by muse, mutect2, varscan2
- RSPH10B | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 92/730 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100521431; called by muse, mutect2, varscan2
- RXRA | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV100709361, COSV62683399; called by muse, mutect2, varscan2
- SEMA5A | c.2706G>T p.W902C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101228704; called by muse, mutect2, varscan2
- SETD1A | c.3274G>A p.V1092M | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.123); catalogued as COSV99353664; called by muse, mutect2, varscan2
- SHANK3 | c.4471A>T p.S1491C | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99437900; called by muse, mutect2, varscan2
- SIL1 | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV99498533; called by muse, mutect2, varscan2
- SIPA1L2 | c.1986T>G p.D662E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99479612; called by muse, mutect2, varscan2
- SLC25A36 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100149224; called by muse, mutect2, varscan2
- SLC25A52 | c.262C>T p.R88* (on ENST00000672005; = p.R78* on NM_001034172.4) | Nonsense Mutation (SNP) | VAF 33/109 reads (30%) | catalogued as COSV52502938; called by muse, mutect2, varscan2
- SNCAIP | c.304G>A p.V102M | Missense Mutation (SNP) | VAF 57/180 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV99750281; called by muse, mutect2, varscan2
- SPDL1 | c.178_179insG p.Y60* | Nonsense Mutation (INS) | VAF 53/151 reads (35%) | catalogued as COSV99517752; called by mutect2, pindel, varscan2
- SVIL | c.5904A>T p.E1968D (on ENST00000355867 / NM_021738.3; = p.E1542D on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100881527; called by muse, mutect2, varscan2
- TIAL1 | c.372-1G>C p.X124_splice | Splice Site (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100958378; called by muse, mutect2, varscan2
- TMTC1 | c.599T>C p.V200A (on ENST00000539277 / NM_001193451.2; = p.V92A on NM_175861.3) | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV55479300; called by muse, mutect2, varscan2
- TRANK1 | c.2518G>C p.G840R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV100084678; called by muse, mutect2, varscan2
- TRIM65 | c.1243A>T p.N415Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV99485586; called by muse, mutect2, varscan2
- TTN | c.98141del p.P32714Lfs*7 (on ENST00000591111; = p.P25290Lfs*7 on NM_003319.4) | Frame Shift Del (DEL) | VAF 47/97 reads (48%) | catalogued as COSV100610668; called by mutect2, pindel, varscan2
- TTN | c.27082C>G p.P9028A (on ENST00000591111; = p.P8101A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/157 reads (54%) | PolyPhen benign (0); catalogued as COSV100628953, COSV59921835; called by muse, mutect2, varscan2
- UBN2 | c.740G>T p.R247L | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757108976, COSV99944447; called by muse, mutect2, varscan2
- WNT2B | c.466C>A p.R156S (on ENST00000369684 / NM_024494.3; = p.R137S on NM_004185.4) | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99861936; called by muse, mutect2, varscan2
- WWP2 | c.44T>A p.F15Y | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV100598756; called by muse, mutect2, varscan2
- ZNF254 | c.129A>T p.L43F | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100298294; called by muse, mutect2, varscan2
- ZNF292 | c.4540A>G p.T1514A | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs780606311, COSV100371179; called by muse, mutect2, varscan2
- ZNF622 | c.994A>G p.K332E | Missense Mutation (SNP) | VAF 82/242 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1227836714, COSV100433178; called by muse, mutect2, varscan2
- AGO2 | c.1758_1759del p.F587Pfs*86 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by pindel, varscan2
- APLF | c.454dup p.I152Nfs*11 | Frame Shift Ins (INS) | VAF 30/123 reads (24%) | called by mutect2, pindel, varscan2
- CDHR5 | c.1174_1179+11delinsCT p.X392_splice | Splice Site (DEL) | VAF 11/30 reads (37%) | called by pindel, varscan2*
- CR1 | c.806_811del p.G269_F270del (on ENST00000367051; = p.G719_F720del on NM_000573.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- CTAGE1 | c.2114del p.S705Ffs*15 | Frame Shift Del (DEL) | VAF 30/109 reads (28%) | called by mutect2, pindel, varscan2
- HSD17B1 | c.698del p.N233Tfs*123 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- KCNT2 | c.1945del p.D649Tfs*17 | Frame Shift Del (DEL) | VAF 20/59 reads (34%) | called by mutect2, pindel, varscan2
- OBSCN | c.15846_15849del p.K5283* | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- PPIL1 | c.382del p.I128Ffs*9 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by mutect2, pindel, varscan2
- RSF1 | c.4233_4234dup p.G1412Vfs*16 | Frame Shift Ins (INS) | VAF 26/96 reads (27%) | called by mutect2, pindel, varscan2
- TRPM1 | c.4637del p.P1546Hfs*15 | Frame Shift Del (DEL) | VAF 18/71 reads (25%) | called by mutect2, pindel, varscan2
- USP14 | c.436del p.M146Wfs*62 | Frame Shift Del (DEL) | VAF 29/82 reads (35%) | called by mutect2, pindel, varscan2
- AC011455.2 | c.999T>C p.L333= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as COSV99671569; called by muse, mutect2, varscan2
- CACNA1A | c.4113C>T p.D1371= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV100803169; called by muse, mutect2, varscan2
- DDX28 | c.72C>T p.L24= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs1479718845, COSV100193138; called by muse, mutect2, varscan2
- DUSP1 | c.705C>A p.S235= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV99496040; called by muse, mutect2, varscan2
- GIMAP8 | c.900C>T p.I300= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV100217696; called by muse, mutect2, varscan2
- GPAT4 | c.1120C>A p.R374= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV101214124; called by muse, mutect2, varscan2
- HTT | c.7987C>A p.R2663= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs765523847, COSV100751225; called by muse, mutect2, varscan2
- MDC1 | c.423C>G p.S141= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV100903066; called by muse, mutect2, varscan2
- MINK1 | c.3738T>C p.D1246= | Silent (SNP) | VAF 30/100 reads (30%) | catalogued as COSV99545342; called by muse, mutect2, varscan2
- MOG | c.510T>G p.T170= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV100973124; called by muse, mutect2, varscan2
- MRPS35 | c.816T>A p.A272= | Silent (SNP) | VAF 89/421 reads (21%) | catalogued as COSV99317639; called by muse, mutect2, varscan2
- NIN | c.2184G>A p.K728= | Silent (SNP) | VAF 39/104 reads (38%) | catalogued as rs1216567931, COSV99815157; called by muse, mutect2, varscan2
- NPSR1 | c.837C>T p.I279= | Silent (SNP) | VAF 38/133 reads (29%) | catalogued as COSV62203224; called by muse, mutect2, varscan2
- OSBPL11 | c.1743A>G p.V581= | Silent (SNP) | VAF 67/128 reads (52%) | catalogued as COSV99954507; called by muse, mutect2
- POU4F3 | c.342C>T p.G114= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100047249; called by muse, mutect2, varscan2
- SLC16A12 | c.1185A>T p.P395= | Silent (SNP) | VAF 34/95 reads (36%) | catalogued as COSV100370522; called by muse, mutect2, varscan2
- SLC40A1 | c.1173A>T p.V391= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV99656518; called by muse, mutect2, varscan2
- SLC7A8 | c.439C>T p.L147= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100382533; called by muse, mutect2, varscan2
- SLIT1 | c.1977C>T p.T659= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs934884957, COSV99822443; called by muse, mutect2, varscan2
- TADA2B | c.1084T>C p.L362= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as COSV99380758; called by muse, mutect2, varscan2
- TBC1D4 | c.3234C>A p.I1078= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV100884805, COSV66492892; called by muse, mutect2, varscan2
- TRIM42 | c.189C>T p.C63= | Silent (SNP) | VAF 48/102 reads (47%) | catalogued as rs751246900, COSV99648816; called by muse, mutect2, varscan2
- ZC3HAV1 | c.361C>T p.L121= | Silent (SNP) | VAF 114/223 reads (51%) | catalogued as COSV99649059; called by muse, varscan2
- ZNF98 | c.186C>T p.I62= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100757615; called by muse, mutect2, varscan2
